Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A7WH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A7WH-01A (Primary Tumor).

[page 1 of 6]
Patient:

Hospital No:
Date of Birth:
Age/Sex:

Pathologist:
Assistant:
Date of Procedure:
Date Received:

Accession Number:

Ordering M.D.:

Copies To:

Location:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES (LYMPH NODE DISSECTION):**
- Seven lymph nodes with no evidence of metastatic carcinoma (0/7)
- B. RIGHT COMMON ILIAC LYMPH NODE (EXCISION):**
- Benign fibrofatty tissue, no lymph nodes identified
- C. LEFT COMMON ILIAC LYMPH NODE (EXCISION):**
- Benign fibrofatty tissue, no lymph nodes identified
- D. LEFT PELVIC LYMPH NODES (LYMPH NODE DISSECTION):**
- Three lymph nodes with no evidence of metastatic carcinoma (0/3)
- E. UTERUS (RADICAL HYSTERECTOMY):**
- Invasive endocervical adenocarcinoma with mucinous features, moderately differentiated
- Tumor location: anterior and posterior ectocervix and lower endocervix
- Tumor size: Posterior cervix - 2.3 cm (longitudinal) x 2.3 cm; Anterior cervix - 1.1 cm (longitudinal) x 0.8 cm
- Maximum depth of invasion: 1.0 cm (thickness of cervical wall 1.4 cm)
- Lymphovascular invasion: Equivocal (retraction artifact and extracellular mucin hamper evaluation)
- Vaginal extension: Not present
- Uterine extension: Not present
- Parametrial involvement: Not present
- Surgical margins: 0.4 cm from deep paracervical/parametrial margin and 1.6 cm from vaginal cuff margin
- Additional Findings:
- Proliferative endometrium
- One left parametrial lymph node with no evidence of metastatic carcinoma (0/1)
- Endocervical reserve cell hyperplasia, squamous metaplasia, and Nabothian cysts
- F. LEFT PELVIC LYMPH NODES (LYMPH NODE DISSECTION):**
- Eleven lymph nodes with no evidence of metastatic carcinoma (0/11)

SYNOPTIC REPORT:

Patient Case(s):

Copy For
Page 1 of 6

ICD-O-3
Adenocarcinoma, mucinous NOS
8480/3
Site: Cervix
c53.9
11/12/13

[page 2 of 6]
PATIENT:

ACCESSION #:

Applies To:

A : RIGHT PELVIC LYMPH NODE
B : RIGHT COMMON ILIAC LYMPH NODE
C : LEFT COMMON ILIAC LYMPH NODE
D : LEFT PELVIC LYMPH NODE
E : UTERUS AND CERVIX
F : LEFT PELVIC LYMPH NODE

Macroscopic

Specimen Type:	Entire uterus
Procedure:	Radical hysterectomy
Other Organs Present:	None
Lymph Node Sampling:	Pelvic lymph nodes Parametrial

Microscopic

Histologic Type:	Adenocarcinoma, mucinous
Histologic Grade:	G2: Moderately differentiated
Tumor Site:	Anterior cervix Posterior cervix
Tumor Size:	Greatest dimension: 3.5cm
Lymphovascular Invasion:	Indeterminate
Margins:	Margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 0.4 cm Closest margin: Deep paracervical/parametrial

Pathologic Staging (pTNM) (AJCC 7th Edition, 2010) [FIGO]

Primary Tumor (pT):	pT1b1 [IB1]: Clinically visible lesion 4.0 cm or less in greatest dimension
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
Number of lymph nodes identified:	22
Number of lymph nodes involved:	0

Uterus, bivalved, posterior half

HISTORY:

Invasive endocervical adenocarcinoma with mucinous features

MICROSCOPIC FINDINGS:

SURGICAL PATHOLOGY REPORT

[page 3 of 6]
PATIENT:

ACCESSION #:

See diagnosis.

GROSS:

A. RIGHT PELVIC LYMPH NODES

Patient name, label:	designated "right pelvic lymph node"
Specimen type:	Lymph node dissection
Received:	In formalin
Specimen contents:	Adipose tissue/lymph node
Number of pieces of tissue:	Multiple
Size of specimen:	2.0 x 1.5 x 0.5 cm in aggregate
Number of lymph nodes:	Possible small lymph nodes
Size of lymph nodes:	Up to 0.5 cm in maximum dimension
Tumor:	No gross tumor seen
Additional findings:	None

The specimen is entirely embedded.

Slide key:

A1. Multiple

B. RIGHT COMMON ILIAC LYMPH NODE

Patient name, label:	designated "right common iliac lymph node"
Specimen type:	Excision
Received:	In formalin
Specimen contents:	Adipose tissue/lymph node
Number of pieces of tissue:	1
Size of specimen:	1.8 x 0.6 x 0.3 cm in aggregate
Number of lymph nodes:	None identified
Size of lymph nodes:	Not applicable
Tumor:	No gross tumor seen
Additional findings:	None

Entire specimen is embedded.

Slide key:

B1. 1

C. LEFT COMMON ILIAC LYMPH NODE

Patient name, label:	designated "left common iliac lymph node"
Specimen type:	Excision
Received:	In formalin
Specimen contents:	Adipose tissue/lymph node
Number of pieces of tissue:	2
Size of specimen:	1.5 x 1.5 x 0.5 cm in aggregate
Number of lymph nodes:	None identified
Size of lymph nodes:	Not applicable
Tumor:	No gross tumor seen
Additional findings:	None

The specimen is entirely embedded.

Slide key:

C1. 2

SURGICAL PATHOLOGY REPORT

[page 4 of 6]
PATIENT:

ACCESSION #:

D. LEFT PELVIC LYMPH NODES

Patient name, label:	designated "left pelvic lymph node"
Specimen type:	Lymph node dissection
Received:	In formalin
Specimen contents:	Adipose tissue/lymph node
Number of pieces of tissue:	Multiple
Size of specimen:	3.5 x 2.5 x 0.8 cm in aggregate
Number of lymph nodes:	Possible small lymph nodes
Size of lymph nodes:	Up to 0.3 cm in greatest dimension
Tumor:	No gross tumor seen
Additional findings:	None

The entire specimen is embedded.

Slide key:

D1. Multiple

E. UTERUS AND CERVIX

Patient name, label:	designated "uterus and cervix"
Specimen type:	Radical hysterectomy
Received:	Fresh for tissue procurement and subsequently fixed in formalin
Specimen integrity:	Intact
Specimen weight:	51.6 grams
Specimen size:	8.0 x 5.0 x 3.0 cm
Overall uterine dimensions:	7.8 x 4.5 x 4.0 cm
Cervix alone:	2.5 cm in length, up to 3.5 cm in diameter
Vaginal cuff:	Present, 2.0 to 2.6 cm in length
Endometrial cavity:	2.5 cm in length, up to 0.7 cm in width
Endometrial thickness:	0.1 cm
Myometrial thickness:	1.5 cm
Left parametrium:	0.6 cm in width
Right parametrium:	0.5 cm in width
Left ovary:	Absent
Left fallopian tube:	Absent
Right ovary:	Absent
Right fallopian tube:	Absent

Pathologic findings:

Tumor:	
Location:	Focally on anterior cervix, mostly on posterior cervix, involving ectocervix and lower endocervical canal
Size:	Anterior cervix - 1.1 (longitudinal) x 0.8 cm; Posterior cervix - 2.3 (longitudinal) x 3.5 cm
Color:	Brown
Consistency:	Soft
Configuration:	Polypoid
Cervical invasion:	Present
Grossly evident vascular invasion:	Absent
Uterine serosal involvement:	Absent
Uterine corpus involvement:	Not identified
Parametrial involvement:	Absent

[page 5 of 6]
PATIENT:

ACCESSION #:

Other Findings:

Non-neoplastic endometrium:	Unremarkable
Endometrial polyp(s):	Not identified
Leiomyoma(s):	Not identified
Other myometrial lesion(s):	Not identified
Uterine serosa:	Unremarkable
Cervix:	As mentioned above
Vaginal cuff:	No gross involvement of vaginal cuff identified
Additional findings:	None

Gross photographs are obtained.

Ink key:

Blue - Vaginal resection margin
Black - posterior uterus
Green (over black) - anterior uterus

A portion of the tumor from center of cervical mass, normal cervix, and normal endometrium is released to the biorepository per standard operating procedure by

Representative sections are submitted.

Slide key:

E1. Right parametrial margin, en face - 2
E2. Left parametrial margin, en face - 1
E3. Uterine corpus - 2
E4-E7. 11:00 to 1:00, tumor and flanking uninvolved cervix including vaginal cuff margin - 1 each
E8. Remainder of right parametrial tissue - 1
E9. Remainder of left parametrial tissue - 1
E10, E11. 5:00, Tumor including vaginal cuff (E10) and endometrium (E11), bisected - 1 each
E12, E13. 8:00 Tumor including vaginal cuff (E12) and endometrium (E13), bisected - 1 each
E14. 3:00, Tumor from posterior cervix - 1
E15. 9:00, Tumor from posterior cervix - 1

F. LEFT PELVIC LYMPH NODES

Patient name, label:	designated "left pelvic lymph nodes"
Specimen type:	Lymph node dissection
Received:	In formalin
Specimen contents:	Adipose tissue/lymph nodes
Number of pieces of tissue:	4
Size of specimen:	3.6 x 2.5 x 0.9 cm in aggregate
Number of lymph nodes:	Multiple possible
Size of lymph nodes:	0.5 to 0.8 cm in maximum dimension
Tumor:	No gross tumor seen
Additional findings:	None

The specimen is entirely embedded.

Slide key:

F1. 2
F2. 2
F3. 1

[page 6 of 6]
PATIENT:

ACCESSION #:

Gross dictated by

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Page 6 of 6

Source: NCI Genomic Data Commons file 62898c19-c04d-4414-afb5-21e5485e8c2b (TCGA-DS-A7WH.069FDE0B-57A4-4398-856D-F3FE511F89B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).